Somatic mutation profile of tumor specimen TCGA-EJ-5524-01A (aliquot TCGA-EJ-5524-01A-01D-1576-08) from TCGA case TCGA-EJ-5524, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.1 years (20,854 days).
Specimen TCGA-EJ-5524-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed28a1ca-4855-484b-8735-6383112b4933.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5524-10A (Blood Derived Normal), aliquot TCGA-EJ-5524-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fd70515-6d1d-4877-993f-a5d93db15ace

The open-access MAF lists 40 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, RNA 2, Splice Region 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.624C>A p.N208K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV55968211, COSV99788704; called by muse, mutect2, varscan2
- ADGRG4 | c.5464C>A p.P1822T | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV54962219; called by muse, mutect2
- ARGFX | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 130/498 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs149102809; called by muse, mutect2, varscan2
- ARHGEF10L | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs753073107, COSV51436121; called by muse, mutect2, varscan2
- ASPG | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.18); catalogued as COSV71934003; called by muse, mutect2, varscan2
- CDH18 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs771062780, COSV56912409, COSV56939656; called by muse, mutect2, varscan2
- CHD2 | c.2896G>C p.E966Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV67712056; called by muse, mutect2, varscan2
- CLCA2 | c.2154C>T p.N718= | Splice Region (SNP) | VAF 32/252 reads (13%) | catalogued as rs140158852; called by muse, mutect2, varscan2
- CNTNAP5 | c.3618T>A p.D1206E | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as COSV70498919; called by muse, mutect2, varscan2
- COL21A1 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV55172434; called by muse, mutect2, varscan2
- DDX42 | c.116T>C p.F39S | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.348); catalogued as COSV63790759; called by muse, mutect2
- FAM83B | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 120/357 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60924600; called by muse, mutect2, varscan2
- FPR1 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1183171485, COSV59053000; called by muse, mutect2, varscan2
- HMCN1 | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 25/487 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV54920867; called by muse, mutect2
- HMGCS2 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs761373362, CM068727, COSV65568000; called by muse, mutect2, varscan2
- HOXD10 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs776732671, COSV99982590; called by muse, mutect2
- KMT2C | c.13319A>G p.Y4440C | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV51471900; called by muse, mutect2, varscan2
- MICB | c.1026G>T p.E342D | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV52856474, COSV52857199; called by muse, mutect2, varscan2
- MUC16 | c.30689C>A p.P10230H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV67480178; called by muse, mutect2
- MX2 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1303776813, COSV58096161, COSV58097421; called by muse, mutect2, varscan2
- PKP2 | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV50738862; called by muse, mutect2
- ROR2 | c.2725G>A p.V909M | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.67); catalogued as rs778811682, COSV65221800; called by muse, mutect2, varscan2
- SEMA6C | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV59005592; called by muse, mutect2
- SMAD3 | c.985G>T p.A329S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.935); catalogued as COSV59287192; called by muse, mutect2, varscan2
- SMARCE1 | c.262A>G p.N88D | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52861463; called by muse, mutect2, varscan2
- TEAD3 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757481197, COSV58816882; called by muse, mutect2
- TTLL11 | c.995G>T p.W332L | Missense Mutation (SNP) | VAF 76/342 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV58649668; called by muse, mutect2, varscan2
- TTYH3 | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51861836; called by muse, mutect2
- TYRO3 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.253); catalogued as COSV55485193; called by muse, mutect2, varscan2
- WDFY3 | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs766953747, COSV55702346; called by muse, mutect2, varscan2
- ARHGAP11A | c.933_937+5del p.X311_splice | Splice Site (DEL) | VAF 14/144 reads (10%) | called by mutect2, pindel
- C1orf174 | c.240C>T p.S80= | Silent (SNP) | VAF 74/223 reads (33%) | catalogued as rs961899892, COSV64365997; called by muse, mutect2, varscan2
- CPS1 | c.99A>G p.R33= | Silent (SNP) | VAF 16/283 reads (6%) | catalogued as COSV51817805; called by muse, mutect2
- DNAH10 | c.9837G>A p.K3279= (on ENST00000409039; = p.K3218= on NM_207437.3) | Silent (SNP) | VAF 14/273 reads (5%) | catalogued as COSV68987326, COSV68997890; called by muse, mutect2
- NAGS | c.1473C>T p.G491= | Silent (SNP) | VAF 33/394 reads (8%) | catalogued as rs1371554521, COSV52813619; called by muse, mutect2
- RECQL5 | c.1233C>T p.C411= | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as COSV58643600; called by muse, mutect2
- WDR7 | c.3612G>A p.L1204= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV54358832; called by muse, mutect2
- C12orf77 | n.418G>A | RNA (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- OR2U1P | n.539C>T | RNA (SNP) | VAF 51/172 reads (30%) | called by muse, mutect2, varscan2
- ZNF99 | c.*50del | 3'UTR (DEL) | VAF 25/185 reads (14%) | called by mutect2, pindel, varscan2
